Somatic mutation profile of tumor specimen TARGET-30-PATTMM-01A (aliquot TARGET-30-PATTMM-01A-01D) from TARGET case TARGET-30-PATTMM, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 0.8 years (276 days).
Specimen TARGET-30-PATTMM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad1635bc-2f3c-4592-943b-16b52b85860b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATTMM-10A (Blood Derived Normal), aliquot TARGET-30-PATTMM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49da6b2f-697e-4278-96c9-eca5b1ae3aea

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC168 | c.17828A>G p.N5943S | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.714); catalogued as COSV59426455; called by muse, mutect2, varscan2
